Somatic mutation profile of tumor specimen TCGA-QR-A6GZ-05A (aliquot TCGA-QR-A6GZ-05A-11D-A35D-08) from TCGA case TCGA-QR-A6GZ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 31.7 years (11,573 days).
Specimen TCGA-QR-A6GZ-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c685059c-4053-459c-9392-82d024c81582.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A6GZ-10A (Blood Derived Normal), aliquot TCGA-QR-A6GZ-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b8490f8-3bcb-42c7-a378-952ae5307262

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F5 | c.3265A>G p.M1089V | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs778357200; called by muse, mutect2
- PPP1R10 | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.14); catalogued as rs1439480776; called by muse, mutect2, varscan2
- GIPC1 | c.560_576del p.L187Rfs*69 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | called by mutect2, pindel, varscan2
- ARHGEF40 | c.3855G>A p.K1285= | Silent (SNP) | VAF 55/157 reads (35%) | called by muse, mutect2, varscan2
- NUTM1 | c.2448G>A p.L816= | Silent (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
